Somatic mutation profile of tumor specimen TCGA-33-AAS8-01A (aliquot TCGA-33-AAS8-01A-11D-A401-08) from TCGA case TCGA-33-AAS8, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.3 years (21,675 days).
Specimen TCGA-33-AAS8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfddada4-51f8-41de-80cd-bca3b4c8225a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-AAS8-11A (Solid Tissue Normal), aliquot TCGA-33-AAS8-11A-11D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6438b95d-202a-4d89-81cc-37852358da8a

The open-access MAF lists 262 somatic variants for this specimen: 196 protein-altering or splice-affecting, 56 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 56, Nonsense Mutation 9, Splice Site 7, Frame Shift Del 7, Intron 5, RNA 4, In Frame Del 2, Splice Region 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTK | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520682, CM097790, CM952230, COSV100437674, COSV58117606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSM2A | c.830G>T p.W277L (on ENST00000219054; = p.W198L on NM_001308169.2) | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392738637, COSV99525445; called by muse, mutect2, varscan2
- ACTRT1 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV100947661; called by muse, mutect2, varscan2
- ADAM11 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as rs763270799, COSV99567632; called by muse, mutect2, varscan2
- ADAMTS18 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1186864593, COSV51398454; called by muse, mutect2, varscan2
- ADGRA3 | c.422T>A p.I141K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99293478; called by muse, mutect2, varscan2
- ADGRG4 | c.3875del p.P1292Hfs*5 | Frame Shift Del (DEL) | VAF 24/81 reads (30%) | catalogued as COSV54959712; called by mutect2, pindel, varscan2
- ADH6 | c.740T>A p.L247* | Nonsense Mutation (SNP) | VAF 94/269 reads (35%) | catalogued as COSV52957109; called by muse, mutect2, varscan2
- APOBEC3D | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 33/158 reads (21%) | catalogued as COSV99329052; called by muse, mutect2, varscan2
- APOL5 | c.25T>A p.L9M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV99968427; called by muse, mutect2, varscan2
- ARHGAP36 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.134); catalogued as COSV99357909; called by muse, mutect2, varscan2
- ARHGEF10L | c.1820A>G p.Q607R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV99393290; called by muse, mutect2, varscan2
- ARHGEF28 | c.3755T>G p.V1252G | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV99709531; called by muse, mutect2, varscan2
- ASAH2 | c.1415-1G>A p.X472_splice | Splice Site (SNP) | VAF 61/124 reads (49%) | catalogued as rs975623984; called by muse, mutect2, varscan2
- ASB9 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100995544; called by muse, mutect2, varscan2
- ASIC5 | c.1406C>G p.T469S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs747060952, COSV101611151, COSV73332984; called by muse, mutect2, varscan2
- ATM | c.8793T>G p.C2931W | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM990223, COSV53725892; called by muse, mutect2, varscan2
- BAIAP3 | c.1726T>C p.Y576H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1206218765, COSV99136300; called by muse, mutect2, varscan2
- BRINP3 | c.2284A>T p.T762S | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.935); catalogued as COSV100819095; called by muse, mutect2, varscan2
- BRINP3 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV100819096, COSV66522458; called by muse, mutect2, varscan2
- C22orf42 | c.168G>C p.K56N | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.188); catalogued as COSV101173352; called by muse, mutect2, varscan2
- CAPS2 | c.806G>C p.R269P | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs931975521, COSV100157944; called by muse, mutect2, varscan2
- CCT6B | c.782A>T p.K261I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV100030837; called by muse, mutect2, varscan2
- CD1E | c.127T>A p.S43T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV100937030; called by muse, mutect2, varscan2
- CD300C | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs755828341, COSV100423286; called by muse, mutect2, varscan2
- CDH8 | c.2042A>G p.D681G | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100182986, COSV100184178; called by muse, mutect2, varscan2
- CENPF | c.3577C>G p.Q1193E | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV100871799, COSV65277100; called by muse, mutect2, varscan2
- CERS1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448786011, COSV55931221; called by muse, mutect2, varscan2
- CHSY3 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100519517; called by muse, mutect2, varscan2
- CLCN5 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs782435783, COSV100260273; called by muse, mutect2, varscan2
- CLVS2 | c.33G>C p.E11D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV99253178; called by muse, mutect2, varscan2
- CMYA5 | c.8558C>T p.T2853I | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs1238547797, COSV101484183; called by muse, mutect2, varscan2
- COL23A1 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456227220, COSV101179308; called by muse, mutect2, varscan2
- COL4A5 | c.991-1G>T p.X331_splice | Splice Site (SNP) | VAF 14/53 reads (26%) | catalogued as CS1413776, COSV100088576; called by muse, mutect2, varscan2
- COL9A1 | c.913-1G>T p.X305_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100295125; called by muse, mutect2, varscan2
- CPT1C | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV99773534; called by muse, mutect2, varscan2
- CXCR4 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.044); catalogued as COSV99603200, COSV99603528; called by muse, mutect2, varscan2
- DACH2 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 23/483 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100913546; called by muse, mutect2
- DACT1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs769869957, COSV60021814; called by muse, mutect2, varscan2
- DCAF12L1 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV100948108; called by muse, mutect2, varscan2
- DCHS1 | c.9742G>T p.A3248S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV100197571; called by muse, mutect2, varscan2
- DLL1 | c.1935G>T p.Q645H | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs766676132, COSV64539088; called by muse, mutect2, varscan2
- DOCK4 | c.3713G>A p.R1238K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV101312835; called by muse, mutect2, varscan2
- DPPA4 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as rs780151445, COSV100169548; called by muse, mutect2, varscan2
- DRP2 | c.2830G>T p.V944L | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV101235240; called by muse, mutect2, varscan2
- DTWD2 | c.281A>T p.H94L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV100407041; called by muse, mutect2, varscan2
- EDN3 | c.437C>A p.P146Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV100285020; called by muse, mutect2, varscan2
- F9 | c.146C>A p.S49* | Nonsense Mutation (SNP) | VAF 65/193 reads (34%) | catalogued as CM010257, COSV99496702; called by muse, mutect2, varscan2
- FAM71A | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99674737; called by muse, mutect2, varscan2
- FASTKD3 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV99241890; called by muse, mutect2, varscan2
- FCGR2A | c.512C>A p.T171N (on ENST00000271450 / NM_001136219.3; = p.T170N on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770453527, COSV99615539; called by muse, mutect2
- FLNC | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100368394; called by muse, mutect2, varscan2
- FOXO4 | c.18G>C p.E6D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100446980; called by muse, mutect2
- GABRA2 | c.1351C>G p.P451A | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as COSV100734541; called by muse, mutect2, varscan2
- GALNT13 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV101223564, COSV67212511; called by muse, mutect2, varscan2
- GALNT3 | c.1738A>G p.K580E | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.049); catalogued as COSV101204979; called by muse, mutect2, varscan2
- GALR1 | c.977C>A p.S326* | Nonsense Mutation (SNP) | VAF 37/117 reads (32%) | catalogued as COSV100231955, COSV100232078, COSV55316248; called by muse, mutect2, varscan2
- GRID1 | c.1249T>A p.S417T | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV100025091, COSV60037698; called by muse, mutect2, varscan2
- GSDME | c.132G>T p.W44C | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100742387; called by muse, mutect2, varscan2
- HBB | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs33937535, CM055961, CM900314, COSV100092818; called by muse, mutect2, varscan2
- HIRA | c.590G>C p.S197T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.584); catalogued as COSV99600629; called by muse, mutect2, varscan2
- HLX | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100854576; called by muse, mutect2, varscan2
- HMCN1 | c.11605G>C p.D3869H | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99632029; called by muse, mutect2, varscan2
- HSPA1B | c.44A>C p.Y15S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100989290; called by muse, mutect2, varscan2
- HTN1 | c.79C>A p.H27N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.136); catalogued as COSV99887544; called by muse, mutect2, varscan2
- HTR2C | c.489C>A p.S163R | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.209); catalogued as COSV99350018; called by muse, mutect2, varscan2
- HYDIN | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99863884; called by muse, mutect2, varscan2
- IL17C | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs373456123; called by muse, mutect2, varscan2
- IRS4 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV100929623; called by muse, mutect2, varscan2
- KCNB1 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100870541; called by muse, mutect2, varscan2
- KCNH1 | c.1676G>A p.C559Y (on ENST00000271751 / NM_172362.3; = p.C532Y on NM_002238.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1487986571, COSV99659966, COSV99660129; called by muse, mutect2, varscan2
- KCNH7 | c.2010C>G p.Y670* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | catalogued as COSV59789745; called by muse, mutect2, varscan2
- KCNN1 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99716140; called by muse, mutect2, varscan2
- KCNQ5 | c.1967A>T p.D656V | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100572457; called by muse, mutect2, varscan2
- KCNT2 | c.1293T>C p.A431= | Splice Region (SNP) | VAF 6/30 reads (20%) | catalogued as rs1414563338, COSV99655114; called by muse, mutect2
- KCTD16 | c.1008G>T p.Q336H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1413206528, COSV101568838; called by muse, mutect2, varscan2
- KDM2B | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as COSV100997509; called by muse, mutect2, varscan2
- KHSRP | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV101231158, COSV101231213; called by muse, mutect2, varscan2
- KIF2B | c.1896T>A p.H632Q | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV99275740; called by muse, mutect2, varscan2
- KLHL34 | c.822C>G p.S274R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV101069958; called by muse, mutect2, varscan2
- KLHL4 | c.1874A>T p.H625L | Missense Mutation (SNP) | VAF 497/560 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100909980; called by muse, mutect2, varscan2
- KRT71 | c.686C>G p.A229G | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV99922294; called by muse, mutect2, varscan2
- LCT | c.1594G>T p.D532Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99929914; called by muse, mutect2, varscan2
- LENG8 | c.2101G>T p.A701S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.191); catalogued as COSV100418121; called by muse, mutect2, varscan2
- LRIT3 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100016249; called by muse, mutect2, varscan2
- LRP5 | c.3218T>C p.V1073A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV99592326; called by muse, mutect2, varscan2
- MAGEA12 | c.145A>T p.T49S | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV100756970; called by muse, mutect2, varscan2
- MMP9 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs143089810; called by muse, varscan2
- MMP9 | c.1663C>T p.L555F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100812432; called by muse, mutect2, varscan2
- MROH2B | c.3246G>A p.M1082I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV101270812, COSV68182304; called by muse, mutect2, varscan2
- MRPL2 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99432224; called by muse, mutect2, varscan2
- MRPS5 | c.673-1G>T p.X225_splice | Splice Site (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99720897; called by muse, mutect2, varscan2
- MRPS5 | c.673-2A>T p.X225_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99720898; called by muse, mutect2, varscan2
- MS4A13 | c.311T>A p.L104H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100981149; called by muse, mutect2, varscan2
- MUC16 | c.42742C>G p.R14248G | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.855); catalogued as COSV101109971; called by muse, varscan2
- MUC17 | c.10390C>A p.P3464T | Missense Mutation (SNP) | VAF 90/293 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.833); catalogued as rs760616549, COSV100074197; called by muse, mutect2, varscan2
- MYH1 | c.3706G>C p.A1236P | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV99876380; called by muse, mutect2, varscan2
- MYH7 | c.1780C>A p.L594M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62521299; called by muse, mutect2, varscan2
- NAA35 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100863376; called by muse, mutect2, varscan2
- NALCN | c.5128G>C p.A1710P | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.312); catalogued as COSV99216309; called by muse, mutect2, varscan2
- NCKAP5 | c.3898C>G p.Q1300E | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs773771235, COSV100493224; called by muse, mutect2, varscan2
- NELFB | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV100546967; called by muse, mutect2, varscan2
- NEXMIF | c.3179C>A p.P1060H | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50050138, COSV99281233; called by muse, mutect2, varscan2
- NFYC | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100438583; called by muse, mutect2, varscan2
- NLGN1 | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs754032397, COSV100849647; called by muse, mutect2, varscan2
- NLGN4X | c.1819G>A p.V607I | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99322787; called by muse, mutect2, varscan2
- NOD2 | c.2222G>A p.W741* | Nonsense Mutation (SNP) | VAF 29/54 reads (54%) | catalogued as rs759074613, COSV100318720; called by muse, mutect2, varscan2
- OR10A7 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100406609; called by muse, mutect2, varscan2
- OR10J5 | c.885G>C p.E295D | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.101); catalogued as COSV100604736; called by muse, mutect2, varscan2
- OR1M1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs151205505; called by muse, mutect2, varscan2
- OR1N1 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV100509790; called by muse, mutect2, varscan2
- OR2T11 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.936); catalogued as COSV100424759, COSV100424886; called by muse, mutect2, varscan2
- OR2W1 | c.508G>T p.G170* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV65851430, COSV65852035; called by muse, mutect2, varscan2
- OR2W3 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs369770600, COSV64457247; called by muse, mutect2, varscan2
- OR52E2 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.07); catalogued as rs149502730; called by muse, mutect2, varscan2
- OR6C4 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); catalogued as rs759165414, COSV101263159; called by muse, mutect2, varscan2
- OR9G4 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV57248275, COSV57248288; called by muse, mutect2, varscan2
- PAK1IP1 | c.1109C>G p.T370S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV101093417; called by muse, mutect2, varscan2
- PAM | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99173613; called by muse, mutect2, varscan2
- PCDH10 | c.2992C>G p.R998G | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.268); catalogued as COSV52102400, COSV99994005; called by muse, mutect2, varscan2
- PDE6C | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV101008800; called by muse, mutect2, varscan2
- PLCB3 | c.2815G>C p.D939H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1346108792, COSV99657561; called by muse, mutect2, varscan2
- PLCB4 | c.3502G>T p.D1168Y (on ENST00000278655 / NM_182797.3; = p.G1180V on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV99596088; called by muse, mutect2, varscan2
- POLR1A | c.4916G>A p.R1639H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747827280, COSV55692443; called by muse, mutect2, varscan2
- PRKCB | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV100334576; called by muse, mutect2, varscan2
- PRKCB | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100334577; called by muse, mutect2, varscan2
- PRPF4 | c.916C>G p.L306V (on ENST00000374198 / NM_001322267.2; = p.L307V on NM_004697.5) | Missense Mutation (SNP) | VAF 103/350 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100950733; called by muse, mutect2, varscan2
- PRSS48 | c.929T>A p.V310D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV101490178; called by muse, mutect2, varscan2
- PRUNE2 | c.4673C>A p.S1558Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.212); catalogued as COSV100944831; called by muse, mutect2, varscan2
- PSD4 | c.1798G>T p.G600C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99831282; called by muse, mutect2, varscan2
- PSKH2 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV99404993; called by muse, mutect2, varscan2
- RAB33A | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99924626; called by muse, mutect2, varscan2
- RELN | c.9460C>A p.L3154I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV100634197; called by muse, mutect2
- RESF1 | c.4092G>C p.L1364F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV100440445; called by muse, mutect2, varscan2
- RHOXF1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.135); catalogued as COSV99483866; called by muse, mutect2, varscan2
- RLIM | c.1400C>A p.S467Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV100223128; called by muse, mutect2, varscan2
- ROBO4 | c.2339C>A p.S780Y | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV100127705; called by muse, mutect2, varscan2
- RPL35A | c.226C>G p.R76G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV99502495; called by muse, mutect2, varscan2
- RUNDC3B | c.1068C>A p.N356K | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100407142; called by muse, mutect2, varscan2
- RYR2 | c.7033G>A p.A2345T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs753156480, COSV100771786; called by muse, mutect2, varscan2
- RYR2 | c.13169A>G p.Q4390R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.138); catalogued as rs763987225, COSV100771791; called by muse, varscan2
- SAMD10 | c.474G>C p.E158D | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99412361; called by muse, mutect2, varscan2
- SCG2 | c.60C>A p.F20L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100544802; called by muse, mutect2, varscan2
- SCN5A | c.1165T>A p.Y389N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100349385; called by muse, mutect2, varscan2
- SELP | c.1243C>A p.R415S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99739833, COSV99741231; called by muse, mutect2, varscan2
- SEMA3E | c.1208G>T p.R403L | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as COSV100319033; called by muse, mutect2, varscan2
- SLC12A1 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV101118981; called by muse, mutect2, varscan2
- SLC1A6 | c.1494G>T p.W498C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99693955; called by muse, mutect2, varscan2
- SLC38A1 | c.236A>T p.N79I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101284235; called by muse, mutect2, varscan2
- SLITRK2 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100157945; called by muse, mutect2, varscan2
- SLITRK2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.279); catalogued as COSV100157947, COSV59423649; called by muse, mutect2, varscan2
- SLITRK2 | c.2489C>A p.P830Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157949; called by muse, mutect2, varscan2
- SLITRK4 | c.1418C>A p.P473Q | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100567416; called by muse, mutect2, varscan2
- SRC | c.611A>T p.H204L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100658138; called by muse, mutect2, varscan2
- SRPK3 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99473275; called by muse, mutect2, varscan2
- STEAP4 | c.758C>A p.T253K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100112637; called by muse, mutect2, varscan2
- SVEP1 | c.10482G>C p.W3494C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99929356; called by muse, mutect2, varscan2
- SYNE1 | c.6953C>T p.T2318I (on ENST00000367255 / NM_182961.4; = p.T2325I on NM_033071.3) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99571309; called by muse, mutect2, varscan2
- SYT9 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100607544, COSV59620833; called by muse, mutect2, varscan2
- TFAP2B | c.940+1G>A p.X314_splice | Splice Site (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99540516; called by muse, mutect2, varscan2
- TMC1 | c.1930C>T p.L644F | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99919989; called by muse, mutect2, varscan2
- TMCC1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100261174; called by muse, mutect2, varscan2
- TMEM132D | c.1199C>A p.T400K | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101398645; called by muse, mutect2, varscan2
- TNN | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.115); catalogued as COSV99512403; called by muse, mutect2, varscan2
- TPTE | c.1373C>T p.T458I (on ENST00000618007 / NM_199261.4; = p.T440I on NM_199259.4) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs761088080; called by muse, mutect2, varscan2
- TTN | c.91565T>A p.L30522H (on ENST00000591111; = p.L23098H on NM_003319.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | PolyPhen probably damaging (0.939); catalogued as COSV100620474; called by muse, mutect2, varscan2
- TTN | c.67412A>T p.K22471I (on ENST00000591111; = p.K15047I on NM_003319.4) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV100620479; called by muse, mutect2, varscan2
- TTN | c.47593C>A p.L15865I (on ENST00000591111; = p.L8441I on NM_003319.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | PolyPhen benign (0.009); catalogued as COSV100620483; called by muse, mutect2, varscan2
- TTN | c.18184C>T p.L6062F (on ENST00000591111; = p.L5135F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | PolyPhen probably damaging (0.999); catalogued as rs1448772446, COSV60174967, COSV60219261; called by muse, mutect2
- TTN | c.16666G>T p.V5556F (on ENST00000591111; = p.V4629F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | PolyPhen benign (0.007); catalogued as COSV100620490; called by muse, mutect2, varscan2
- USH2A | c.2356G>T p.G786W | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100238347; called by muse, mutect2, varscan2
- USP9X | c.1599A>G p.I533M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100199711; called by muse, mutect2, varscan2
- USP9X | c.5739C>G p.D1913E | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV100199712, COSV61065692; called by muse, mutect2, varscan2
- XAB2 | c.1503G>A p.Q501= | Splice Region (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99351294; called by muse, mutect2, varscan2
- XIRP2 | c.7784A>G p.H2595R (on ENST00000628543; = p.H2770R on NM_152381.6) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1416296429, COSV99745018; called by muse, mutect2, varscan2
- ZDHHC15 | c.634C>A p.H212N | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100973812; called by muse, mutect2, varscan2
- ZGRF1 | c.1433C>G p.S478C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); catalogued as COSV100005642; called by muse, mutect2, varscan2
- ZNF284 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.358); catalogued as COSV101399033; called by muse, mutect2, varscan2
- ZNF326 | c.98-2A>T p.X33_splice | Splice Site (SNP) | VAF 30/55 reads (55%) | catalogued as COSV100438200; called by muse, mutect2, varscan2
- ZNF578 | c.767A>G p.E256G | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as COSV101405085; called by muse, mutect2, varscan2
- ZNF655 | c.1266C>A p.C422* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99402225; called by muse, mutect2, varscan2
- ZNF668 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs919271870, COSV56218117; called by muse, mutect2
- ZNF804A | c.1803G>T p.K601N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1420931382, COSV100168884; called by muse, mutect2, varscan2
- AGPAT5 | c.686del p.T229Rfs*19 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- AHNAK | c.11207del p.P3736Qfs*5 | Frame Shift Del (DEL) | VAF 47/185 reads (25%) | called by mutect2, pindel, varscan2
- ARL14EP | c.70dup p.R24Pfs*6 | Frame Shift Ins (INS) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- HNF1B | c.506A>C p.Y169S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.46+1del | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- IGSF22 | c.718del p.L240Wfs*17 | Frame Shift Del (DEL) | VAF 56/202 reads (28%) | called by mutect2, pindel, varscan2
- RSPH10B2 | c.2399A>C p.Q800P | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.276); called by mutect2, varscan2
- RTL3 | c.1328del p.R443Pfs*62 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- SLC44A4 | c.769del p.L257Wfs*5 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- SLC9C2 | c.1148_1195del p.V383_K399delinsE | In Frame Del (DEL) | VAF 35/171 reads (20%) | called by mutect2, pindel
- SSH3 | c.404_406del p.E135del | In Frame Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel
- ABHD13 | c.612T>A p.S204= | Silent (SNP) | VAF 43/82 reads (52%) | catalogued as COSV101024213; called by muse, mutect2, varscan2
- ACCSL | c.822C>T p.S274= | Silent (SNP) | VAF 108/392 reads (28%) | catalogued as COSV101122237; called by muse, mutect2, varscan2
- ACTRT1 | c.387C>A p.T129= | Silent (SNP) | VAF 53/203 reads (26%) | catalogued as COSV100947660; called by muse, mutect2, varscan2
- AHNAK | c.8751C>T p.N2917= | Silent (SNP) | VAF 108/340 reads (32%) | catalogued as COSV99948422; called by muse, mutect2
- AMIGO3 | c.1305A>C p.V435= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV100246655; called by muse, mutect2, varscan2
- AOC2 | c.1104C>T p.A368= | Silent (SNP) | VAF 37/186 reads (20%) | catalogued as rs754467491, COSV53198652; called by muse, mutect2, varscan2
- AVPR1B | c.75C>A p.P25= | Silent (SNP) | VAF 50/182 reads (27%) | catalogued as rs368799737, COSV65638142; called by muse, mutect2, varscan2
- BPIFB6 | c.873C>T p.T291= | Silent (SNP) | VAF 69/208 reads (33%) | catalogued as COSV100848535; called by muse, mutect2, varscan2
- C5 | c.2556G>T p.G852= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99798279; called by muse, mutect2, varscan2
- CCDC141 | c.2694G>A p.E898= | Silent (SNP) | VAF 83/266 reads (31%) | catalogued as COSV99837086; called by muse, mutect2, varscan2
- CLCN4 | c.1338C>T p.A446= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as COSV101073913; called by muse, mutect2, varscan2
- DAXX | c.1275G>A p.Q425= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99802355; called by muse, mutect2, varscan2
- DMRTA1 | c.1512G>T p.P504= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs111683201, COSV100364813; called by muse, mutect2, varscan2
- DMRTC1 | c.498C>G p.P166= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2
- DNAH7 | c.3771T>C p.N1257= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- EDA | c.936C>A p.I312= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1454299730, CM1313216, COSV101000072; called by muse, mutect2, varscan2
- FAM13C | c.1428C>G p.L476= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV53254859, COSV99514197; called by muse, mutect2, varscan2
- FBXO15 | c.247C>T p.L83= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1435755675, COSV99503528; called by muse, mutect2, varscan2
- GALNT11 | c.1767C>T p.G589= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100231927; called by muse, mutect2, varscan2
- GRIN2C | c.3549G>A p.G1183= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99501194; called by muse, mutect2
- GRM5 | c.1584C>A p.V528= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs1008688144, COSV100553050; called by muse, mutect2, varscan2
- HERC2 | c.435G>C p.V145= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV99875184; called by muse, mutect2, varscan2
- HPX | c.441G>T p.V147= | Silent (SNP) | VAF 47/161 reads (29%) | catalogued as COSV99793412; called by muse, mutect2, varscan2
- IBSP | c.813C>T p.Y271= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1304341987, COSV56895135; called by muse, mutect2, varscan2
- ILK | c.765T>C p.G255= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV100196507; called by muse, mutect2, varscan2
- KALRN | c.5580A>T p.L1860= (on ENST00000360013 / NM_001024660.4; = p.L163= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs1264487813, COSV99362456; called by muse, mutect2, varscan2
- KMT2D | c.7422C>T p.P2474= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99983771; called by muse, mutect2, varscan2
- KRT73 | c.300G>T p.P100= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV99988665; called by muse, mutect2, varscan2
- LRP1B | c.1125G>T p.L375= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV101258032; called by muse, mutect2, varscan2
- MAP7D3 | c.861A>T p.V287= | Silent (SNP) | VAF 72/248 reads (29%) | catalogued as COSV100286488; called by muse, mutect2, varscan2
- MDM1 | c.1230A>G p.P410= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV100291955; called by muse, mutect2, varscan2
- MPPE1 | c.432A>G p.R144= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100013314; called by muse, mutect2, varscan2
- MTAP | c.378T>C p.D126= | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as COSV101205484; called by muse, mutect2, varscan2
- NCAM2 | c.1548C>T p.F516= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs1436773351, COSV99523947; called by muse, mutect2, varscan2
- NLGN1 | c.1137C>G p.L379= | Silent (SNP) | VAF 236/327 reads (72%) | catalogued as COSV100849646; called by muse, mutect2, varscan2
- OR11H1 | c.186C>A p.P62= | Silent (SNP) | VAF 18/104 reads (17%) | called by mutect2, varscan2
- OR8K3 | c.480C>A p.T160= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV100449825; called by muse, mutect2, varscan2
- PTPRU | c.3093C>G p.A1031= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV100113214; called by muse, mutect2, varscan2
- RSPO1 | c.219C>G p.G73= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV100740641; called by muse, mutect2, varscan2
- RYR3 | c.5196G>T p.L1732= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV101213190; called by muse, mutect2, varscan2
- SATB1 | c.1716C>T p.N572= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs780251058, COSV100113319, COSV58673929; called by muse, mutect2, varscan2
- SLC1A6 | c.489G>T p.L163= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV55672317, COSV99693960; called by muse, mutect2
- SLCO1B1 | c.1911T>A p.L637= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs1273677384, COSV57016846; called by muse, mutect2, varscan2
- SPATS1 | c.513C>A p.L171= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV99913525; called by muse, mutect2, varscan2
- STAB2 | c.777G>C p.R259= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV101186137; called by muse, mutect2, varscan2
- SYNE1 | c.17025G>A p.L5675= (on ENST00000367255 / NM_182961.4; = p.L5604= on NM_033071.3) | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99571301; called by muse, mutect2
- SYT9 | c.1059G>C p.L353= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV100608598; called by muse, mutect2, varscan2
- TBC1D8B | c.2466A>T p.V822= | Silent (SNP) | VAF 96/281 reads (34%) | catalogued as COSV99344672; called by muse, mutect2, varscan2
- TBXT | c.1230C>A p.I410= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV51617290, COSV99752699; called by muse, mutect2, varscan2
- TH | c.1392G>C p.V464= (on ENST00000381178 / NM_199292.3; = p.V433= on NM_000360.4) | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99171155; called by muse, mutect2, varscan2
- TNK2 | c.2832A>G p.P944= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1224108291, COSV100361488; called by muse, mutect2
- TRPC5 | c.591G>T p.L197= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as COSV53298183, COSV99461745; called by muse, mutect2, varscan2
- TTN | c.21006A>T p.T7002= (on ENST00000591111; = p.T6075= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100620486; called by muse, mutect2, varscan2
- TTN | c.8607G>T p.G2869= (on ENST00000591111; = p.G2823= on NM_003319.4) | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV100620493; called by muse, mutect2, varscan2
- UCK1 | c.312C>T p.I104= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs370115943; called by muse, mutect2
- VPS16 | c.2073C>T p.F691= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV66797414; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848417 C>A | 5'Flank (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- CCDC33 | c.2139+14del | Intron (DEL) | VAF 25/90 reads (28%) | catalogued as rs774731701; called by mutect2, pindel, varscan2
- ELMOD1 | c.-86+921C>A | Intron (SNP) | VAF 18/48 reads (38%) | catalogued as rs200450901, COSV99760192; called by muse, mutect2, varscan2
- FOLH1B | n.1439T>C | RNA (SNP) | VAF 57/212 reads (27%) | called by muse, mutect2, varscan2
- LINC01588 | n.763G>A | RNA (SNP) | VAF 62/138 reads (45%) | called by muse, mutect2, varscan2
- MIR323B | n.12G>T | RNA (SNP) | VAF 10/26 reads (38%) | catalogued as rs1297189711; called by muse, mutect2, varscan2
- MIR514A3 | n.73G>T | RNA (SNP) | VAF 18/77 reads (23%) | called by mutect2, varscan2
- PAX2 | c.1090+230C>T | Intron (SNP) | VAF 16/43 reads (37%) | catalogued as COSV62291550; called by muse, mutect2, varscan2
- SAMHD1 | c.1504-490T>G | Intron (SNP) | VAF 25/100 reads (25%) | catalogued as COSV99456029; called by muse, mutect2, varscan2
- TTN | c.10361-3662A>T | Intron (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100620492; called by muse, mutect2, varscan2
